Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RB-01A (Primary Tumor).

[page 1 of 2]
Histology

* Final Report *

Result Type: Histology
Result Date:
Result Status:
Result Title:
Performed By:
Verified By:
Encounter Info:

1CD-0-3
Carcinoma, Squamous cell, NOS 8070/3
Site: Cervix, NOS C53.9
lw 9/8/11

* Final Report *

(Verified)

Patient Name: Lab Accession #:
Patient DOB: Age: Collection Date:
Accession Date:
Sign Out Date:

Tissue Source:
1: CERVIX #1 FOR FS
2: CERVIX #2
3: VAGINA: NORMAL
4: CERVIX

Final Diagnosis:

1. Cervix, #1 (biopsy):

- Squamous cell carcinoma, invasive, moderately differentiated margins involved (see note).

Note: Although the orientation of the biopsy is not optimal, the tumor near completely replaces the entire cervical stroma and measures greater than 5 mm in greatest thickness.

2. Cervix, #2 (biopsy):

- Fragments of invasive squamous cell carcinoma, moderate to poorly differentiated.

3. Vaginal mucosa for study, normal (biopsy):

- Mucosal tissue (gross diagnosis only).

Note: The specimen was submitted in its entirety for the protocol study.

4. Cervix (biopsy):

- Squamous cell carcinoma, invasive, moderate to poorly differentiated.

Intraoperative Consult Diagnosis:

Frozen section diagnosis:

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Histology

* Final Report *

Labelled "cervix #1, biopsy" (FS x 1, TP x 2):

- Invasive squamous cell carcinoma.

Gross Description:

Part 1. Received fresh for frozen section and subsequently placed in formalin is a 1.0 x 0.7 x 0.2 cm portion of red-pink tissue that is entirely submitted for frozen section and two H&E touch preps are made. The specimen is forwarded for routine histological processing in its entirety.

1 – frozen section remnant tissue. 1 piece.

Part 2. Labelled "cervix #2 : tumor". Received fresh and subsequently placed in formalin is a 1.4 x 0.6 x 0.3 cm portion of tan-grey, granular, friable tissue. A portion of the specimen is submitted for the study and the remainder is trisected and forwarded for routine histological processing.

1 – 3 pieces, x 3.

Part 3. Received fresh and subsequently placed in formalin is a 0.3 x 0.2 x 0.2 cm portion of vaginal mucosa which is entirely submitted for study. No tissue is submitted for histological processing.

Part 4. Labelled "cervix". Received in formalin is a 1.7 x 0.6 x 0.4 cm fragment of grey-pink, markedly friable, granular tissue with no ectocervical mucosa or possible resection margin grossly identified. The specimen is entirely submitted for routine histological processing.

1 – 1 piece.

Note: tissue may fragment upon processing.

Primary Pathologist:

Completed Action List:

- * Order by
- * Perform
- * VERIFY by
- * Assist by on

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 502bac41-1a16-4a5c-84ae-9bb9d93b93c8 (TCGA-EK-A2RB.F973731C-16D2-4391-ACCF-381C362B8438.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).